Somatic mutation profile of tumor specimen 0DBFCF from CCDI case PBBKSJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.2 years (3,009 days).
Specimen 0DBFCF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1da669aa-391f-4508-9ef3-a2d364827f60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBFC7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a521539-1fe9-43d8-b6b6-50a7d0d59700

The open-access MAF lists 25 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 6, Silent 3, 3'UTR 2, Nonsense Mutation 1, Splice Site 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MFSD8 | c.863+1G>A p.X288_splice | Splice Site (SNP) | VAF 285/689 reads (41%) | catalogued as rs200319160, CS091348; ClinVar: pathogenic; called by muse, varscan2
- KCNG2 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs746404020; called by muse, mutect2, varscan2
- MACC1 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 119/716 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs535198484, COSV100255314; called by muse, mutect2, varscan2
- AC105001.2 | c.140C>A p.A47D | Missense Mutation (SNP) | VAF 133/322 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, varscan2
- CFAP46 | c.534G>C p.M178I | Missense Mutation (SNP) | VAF 74/400 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CREB3L2 | c.729dup p.S244Lfs*14 | Frame Shift Ins (INS) | VAF 82/586 reads (14%) | called by mutect2, varscan2
- ECT2 | c.2559_2560insACTTCTTCCCTCCACTGAGCCGTGGGATGTCATAAGAGCCCTTCGAAGA p.A854Tfs*6 (on ENST00000392692 / NM_001349098.2; = p.A823Tfs*6 on NM_018098.6 and 2 other RefSeq transcripts) | Nonsense Mutation (INS) | VAF 16/892 reads (2%) | called by muse*, mutect2
- FZD8 | c.374A>T p.Y125F | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.972); called by muse, mutect2
- OXCT1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 65/338 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- PCDHB5 | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- PTPRM | c.917C>A p.S306Y | Missense Mutation (SNP) | VAF 93/609 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- SLC10A4 | c.1087T>C p.F363L | Missense Mutation (SNP) | VAF 32/987 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- TNXB | c.6050C>T p.T2017I (on ENST00000647633; = p.T1770I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/710 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ZXDB | c.281T>C p.L94P | Missense Mutation (SNP) | VAF 127/306 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FOXC2 | c.699C>T p.P233= | Silent (SNP) | VAF 33/172 reads (19%) | called by mutect2, varscan2
- IKZF2 | c.264C>T p.S88= | Silent (SNP) | VAF 127/508 reads (25%) | catalogued as rs374835918; called by muse, mutect2, varscan2
- ZNF165 | c.810A>T p.I270= | Silent (SNP) | VAF 93/721 reads (13%) | called by muse, mutect2, varscan2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- ADGRG6 | c.*216T>A | 3'UTR (SNP) | VAF 8/62 reads (13%) | called by muse, varscan2
- ANKRD40CL | c.285+85A>C | Intron (SNP) | VAF 18/116 reads (16%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 18/180 reads (10%) | called by muse, varscan2
- CEP43 | c.301-89T>C | Intron (SNP) | VAF 13/145 reads (9%) | called by muse, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 6/76 reads (8%) | called by mutect2, varscan2
- PRPF31 | c.527+80G>A | Intron (SNP) | VAF 5/35 reads (14%) | called by muse, varscan2
- UTP6 | c.544-81T>C | Intron (SNP) | VAF 17/230 reads (7%) | called by muse, mutect2
